CCDI case PBBXAI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/2a0b5ac8-6a82-43ac-b056-14ab69c43514

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Angiomatoid fibrous histiocytoma: ICD-O-3 morphology code: 8836/1; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Age at diagnosis: 11.3 years (4,137 days).

Biospecimens (3 samples)
- Sample 0DJPCL: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DJPCS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DJPD7: Tissue type: Tumor; Specimen type: Solid Tissue.
